Gene-level copy-number profile of tumor specimen TCGA-CC-5261-01A from TCGA case TCGA-CC-5261, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 44.8 years (16,373 days).
Specimen TCGA-CC-5261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.3d6f29ce-a518-4cee-a3f8-f645968c1785.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-5261-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a3345608-b18a-4c72-9883-e923014aed01

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 727; copy number 2: 16,037; copy number 3: 25,614; copy number 4: 6,766; copy number 5: 4,876; copy number 6: 1,674; copy number 7: 1,504; copy number 8: 2,561; copy number 9: 56.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-5261-01A-01D-A12Y-01): tumor purity 0.49, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,121 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 8–9 (broad region; genes not listed).
- chr13:61,409,685–98,024,296, 355 genes, copy number 7 (broad region; genes not listed).
- chr13:100,708,325–101,059,286, 1 gene, copy number 7 (within-gene range 6–7): NALCN-AS1.
- chr13:100,934,023–110,129,136, 95 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr14:18,333,726–26,208,424, 484 genes, copy number 7–8 (broad region; genes not listed).
- chr14:40,630,006–48,491,767, 71 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr20:6,200,989–22,886,068, 243 genes, copy number 7 (broad region; genes not listed).
- chr20:54,208,087–64,313,132, 268 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
